Somatic mutation profile of tumor specimen MMRF_2330_2_BM_CD138pos (aliquot MMRF_2330_2_BM_CD138pos_T1_KHS5U_L16539) from MMRF case MMRF_2330, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.4 years (21,343 days).
Specimen MMRF_2330_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e62bf07-2484-4c00-b546-9bf29629e33a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2330_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2330_1_PB_Whole_C1_KHS5U_K14051; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d5ae40a-7b23-4f4c-bf62-83e26968e5dc

The open-access MAF lists 105 somatic variants for this specimen: 39 protein-altering or splice-affecting, 20 silent, 46 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, 3'UTR 28, Silent 20, Intron 12, 5'UTR 3, RNA 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAMKV | c.1276G>A p.A426T | Missense Mutation (SNP) | VAF 94/192 reads (49%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as rs773741414; called by muse, mutect2, varscan2
- CRTC2 | c.1459C>T p.P487S | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.119); catalogued as COSV57846459; called by muse, mutect2, varscan2
- CT47B1 | c.705G>T p.K235N | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs746898363; called by muse, varscan2
- EIF2AK1 | c.1787A>C p.K596T | Missense Mutation (SNP) | VAF 99/268 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1320565463; called by muse, mutect2, varscan2
- EIF4G3 | c.2398A>G p.I800V | Missense Mutation (SNP) | VAF 6/165 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.345); catalogued as rs1471689931; called by muse, mutect2
- FRMD8 | c.1034C>T p.T345I | Missense Mutation (SNP) | VAF 79/139 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as rs1342232949; called by muse, mutect2, varscan2
- IGHV1-69 | c.265A>G p.I89V | Missense Mutation (SNP) | VAF 106/146 reads (73%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs374017972; called by muse, mutect2, varscan2
- IGHV2-70 | c.295G>C p.V99L | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.708); catalogued as rs765459987; called by muse, varscan2
- IGHV2-70 | c.152G>C p.S51T | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs372640551; called by muse, varscan2
- IGHV2-70 | c.107C>T p.T36I | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs548028630; called by muse, varscan2
- IGHV2-70 | c.8T>A p.I3K | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs374765470; called by muse, mutect2, varscan2
- IGHV3-30 | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.935); catalogued as rs572918042; called by muse, mutect2, varscan2
- IGKV4-1 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as rs188769218; called by muse, mutect2
- IGLV3-25 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 76/259 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs181874336; called by muse, mutect2, varscan2
- LAMC3 | c.2446G>A p.V816M | Missense Mutation (SNP) | VAF 97/315 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as rs576989735, COSV63090250; called by muse, mutect2, varscan2
- LRRTM4 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 16/223 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV69139056; called by muse, mutect2
- PCDHA3 | c.550A>T p.R184* | Nonsense Mutation (SNP) | VAF 44/160 reads (28%) | catalogued as COSV65367975; called by muse, mutect2, varscan2
- POLM | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs774514038; called by muse, mutect2, varscan2
- SNX20 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs375118669; called by muse, mutect2, varscan2
- ADNP | c.2162A>G p.Q721R | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAD | c.1384C>G p.Q462E | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- CCNL1 | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- DNAH5 | c.1856A>G p.N619S | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- DOLK | c.634T>G p.S212A | Missense Mutation (SNP) | VAF 56/239 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DSP | c.8516C>A p.S2839Y | Missense Mutation (SNP) | VAF 82/193 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- FOXK1 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- GSDMC | c.158C>A p.S53Y | Missense Mutation (SNP) | VAF 70/260 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- HSPA4L | c.1268A>G p.N423S | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGHV2-70D | c.215T>G p.I72S | Missense Mutation (SNP) | VAF 70/88 reads (80%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, varscan2
- INTS13 | c.1648C>T p.H550Y | Missense Mutation (SNP) | VAF 99/242 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LRRC9 | c.2462G>A p.G821E | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MKI67 | c.2516G>A p.G839E | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- OTOG | c.1237C>A p.L413I | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- P2RY8 | c.202A>G p.T68A | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- PLA2G4A | c.1597C>G p.R533G | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- PROM1 | c.389T>A p.F130Y | Missense Mutation (SNP) | VAF 66/175 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RANBP2 | c.4630G>A p.E1544K | Missense Mutation (SNP) | VAF 71/230 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- ST3GAL3 | c.728T>C p.L243P (on ENST00000361392 / NM_174964.4; = p.L228P on NM_006279.5) | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- WDFY3 | c.2051T>C p.L684P | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- AKR7A3 | c.990C>T p.F330= | Silent (SNP) | VAF 151/404 reads (37%) | catalogued as rs1355716323; called by muse, mutect2
- AOC2 | c.522G>A p.Q174= | Silent (SNP) | VAF 11/293 reads (4%) | called by muse, mutect2
- ARID4A | c.1797T>G p.T599= | Silent (SNP) | VAF 75/173 reads (43%) | called by muse, mutect2, varscan2
- ASB4 | c.564G>A p.S188= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV100367098, COSV57945702; called by muse, mutect2
- BTD | c.951G>A p.V317= | Silent (SNP) | VAF 52/203 reads (26%) | called by muse, mutect2, varscan2
- FBXW7 | c.1065C>T p.Y355= (on ENST00000281708 / NM_001349798.2; = p.Y275= on NM_018315.5) | Silent (SNP) | VAF 17/256 reads (7%) | catalogued as rs761044375; called by muse, mutect2
- FYN | c.1494C>T p.L498= | Silent (SNP) | VAF 67/153 reads (44%) | catalogued as rs751427070; called by muse, mutect2, varscan2
- HEXB | c.841C>A p.R281= | Silent (SNP) | VAF 126/442 reads (29%) | called by muse, mutect2, varscan2
- KIAA1958 | c.1890C>T p.Y630= | Silent (SNP) | VAF 55/218 reads (25%) | catalogued as COSV61725230; called by muse, mutect2, varscan2
- LTB | c.168G>A p.T56= | Silent (SNP) | VAF 148/359 reads (41%) | catalogued as rs749707085, COSV53000372; called by muse, mutect2, varscan2
- LZTS2 | c.1653C>T p.L551= | Silent (SNP) | VAF 34/75 reads (45%) | called by muse, mutect2, varscan2
- RAPGEFL1 | c.1068G>A p.A356= | Silent (SNP) | VAF 38/63 reads (60%) | catalogued as rs139857191; called by muse, mutect2, varscan2
- SEZ6L | c.156G>A p.P52= | Silent (SNP) | VAF 170/452 reads (38%) | catalogued as rs778789856; called by muse, mutect2, varscan2
- SLC45A4 | c.1917G>C p.L639= (on ENST00000517878 / NM_001286646.2; = p.L588= on NM_001080431.2) | Silent (SNP) | VAF 10/118 reads (8%) | catalogued as COSV99198761; called by muse, mutect2
- SPN | c.1071G>A p.A357= | Silent (SNP) | VAF 47/126 reads (37%) | catalogued as rs914647648; called by muse, mutect2, varscan2
- TAAR6 | c.378C>A p.I126= | Silent (SNP) | VAF 11/287 reads (4%) | called by muse, mutect2
- TDRD5 | c.2445G>A p.L815= | Silent (SNP) | VAF 61/183 reads (33%) | catalogued as rs763127224; called by muse, mutect2, varscan2
- TMEM63C | c.747C>T p.V249= | Silent (SNP) | VAF 11/154 reads (7%) | catalogued as rs373396890; called by muse, mutect2
- TRPM4 | c.2976C>T p.N992= | Silent (SNP) | VAF 13/200 reads (7%) | called by muse, mutect2
- ZNF77 | c.1182C>T p.Y394= | Silent (SNP) | VAF 51/129 reads (40%) | catalogued as rs1331370549; called by muse, mutect2, varscan2
- AC009729.1 | n.514T>A | RNA (SNP) | VAF 58/101 reads (57%) | called by muse, mutect2, varscan2
- AC123912.3 | n.637C>A | RNA (SNP) | VAF 52/206 reads (25%) | called by muse, mutect2, varscan2
- ADARB2 | c.*198C>A | 3'UTR (SNP) | VAF 8/162 reads (5%) | called by muse, mutect2
- ADO | c.*425T>G | 3'UTR (SNP) | VAF 27/71 reads (38%) | called by muse, mutect2, varscan2
- ARHGAP5 | c.*2179A>G | 3'UTR (SNP) | VAF 61/155 reads (39%) | catalogued as rs1045599170; called by muse, mutect2, varscan2
- COL4A4 | c.*2906C>T | 3'UTR (SNP) | VAF 52/142 reads (37%) | catalogued as rs775355828; called by muse, mutect2, varscan2
- CST4 | c.*227C>T | 3'UTR (SNP) | VAF 15/92 reads (16%) | called by muse, mutect2, varscan2
- DDX54 | c.*1385T>C | 3'UTR (SNP) | VAF 12/20 reads (60%) | called by muse, mutect2, varscan2
- DNAAF3 | c.*330C>T | 3'UTR (SNP) | VAF 37/103 reads (36%) | called by muse, mutect2, varscan2
- DNM3 | c.1911+1559T>A | Intron (SNP) | VAF 50/87 reads (57%) | called by muse, mutect2, varscan2
- EIF2AK2 | c.*6657T>G | 3'UTR (SNP) | VAF 7/65 reads (11%) | called by muse, mutect2, varscan2
- FAM174B | c.-42G>A | 5'UTR (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- FBXO40 | c.*3050T>G | 3'UTR (SNP) | VAF 63/104 reads (61%) | called by muse, mutect2, varscan2
- FSHB | c.*127C>T | 3'UTR (SNP) | VAF 30/112 reads (27%) | catalogued as rs927511854; called by muse, mutect2, varscan2
- GPR179 | c.*510A>G | 3'UTR (SNP) | VAF 22/34 reads (65%) | catalogued as rs1468940627; called by muse, mutect2, varscan2
- GPR55 | c.-98G>A | 5'UTR (SNP) | VAF 52/168 reads (31%) | called by muse, mutect2, varscan2
- GULP1 | c.844-602T>A | Intron (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- HSPA4L | c.*321T>A | 3'UTR (SNP) | VAF 46/109 reads (42%) | called by muse, mutect2, varscan2
- IRF2BP2 | c.*1557G>T | 3'UTR (SNP) | VAF 44/78 reads (56%) | called by muse, mutect2, varscan2
- KANSL1 | c.1289+29C>G | Intron (SNP) | VAF 72/362 reads (20%) | called by muse, varscan2
- LINC01553 | n.1263G>C | RNA (SNP) | VAF 34/416 reads (8%) | called by muse, mutect2
- LRR1 | c.184-804G>C | Intron (SNP) | VAF 26/57 reads (46%) | called by muse, mutect2
- LRRC1 | c.*233A>C | 3'UTR (SNP) | VAF 23/60 reads (38%) | called by muse, mutect2, varscan2
- MBOAT2 | c.*3494T>A | 3'UTR (SNP) | VAF 55/142 reads (39%) | called by muse, mutect2, varscan2
- MECP2 | c.*5188T>A | 3'UTR (SNP) | VAF 52/175 reads (30%) | called by muse, mutect2, varscan2
- MSI2 | c.727+4536G>A | Intron (SNP) | VAF 62/292 reads (21%) | called by muse, mutect2, varscan2
- NEGR1 | c.*2928A>G | 3'UTR (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- NKX6-3 | c.*259C>G | 3'UTR (SNP) | VAF 99/170 reads (58%) | called by muse, mutect2, varscan2
- NME1 | c.-5+497del | Intron (DEL) | VAF 18/130 reads (14%) | catalogued as rs201290301, COSV50148304; called by pindel, varscan2
- NR2F2 | c.*637G>T | 3'UTR (SNP) | VAF 26/147 reads (18%) | called by muse, mutect2, varscan2
- NUDT21 | c.*3545T>C | 3'UTR (SNP) | VAF 31/46 reads (67%) | called by muse, mutect2, varscan2
- OPRD1 | c.*262G>A | 3'UTR (SNP) | VAF 38/79 reads (48%) | catalogued as rs904614483; called by muse, mutect2, varscan2
- PC | c.1368+3305G>T | Intron (SNP) | VAF 26/108 reads (24%) | called by muse, mutect2, varscan2
- PCDHA6 | c.-84A>T | 5'UTR (SNP) | VAF 12/303 reads (4%) | catalogued as rs1427962519; called by muse, mutect2
- PDYN | c.*1134del | 3'UTR (DEL) | VAF 25/73 reads (34%) | called by mutect2, pindel, varscan2
- PKHD1L1 | c.10828+71T>A | Intron (SNP) | VAF 32/107 reads (30%) | called by muse, mutect2, varscan2
- PTPRE | c.*2506T>C | 3'UTR (SNP) | VAF 12/132 reads (9%) | called by muse, mutect2
- RASGEF1B | c.438+592A>C | Intron (SNP) | VAF 28/75 reads (37%) | called by muse, mutect2, varscan2
- RPS27L | c.226+637A>C | Intron (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
- TFCP2L1 | c.*5227T>C | 3'UTR (SNP) | VAF 28/307 reads (9%) | called by muse, mutect2
- TNIK | c.*1715dup | 3'UTR (INS) | VAF 32/122 reads (26%) | catalogued as rs1004561186; called by mutect2, varscan2
- TREML2 | c.*776C>T | 3'UTR (SNP) | VAF 39/109 reads (36%) | called by muse, mutect2, varscan2
- TSPAN5 | c.*1537T>G | 3'UTR (SNP) | VAF 30/123 reads (24%) | called by muse, mutect2, varscan2
- USP20 | c.2513-28G>C | Intron (SNP) | VAF 44/158 reads (28%) | called by muse, mutect2, varscan2
- VSTM5 | c.*475C>G | 3'UTR (SNP) | VAF 58/189 reads (31%) | called by muse, mutect2, varscan2
- ZNF414 | c.875-31A>G | Intron (SNP) | VAF 8/170 reads (5%) | called by muse, mutect2
